Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACS, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACS-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : HCC

Gross Photo :

GROSS:

Specimen:

Liver: 7.6 x 7.0 x 3.2 cm, unfixed

Gallbladder:

5.8 cm in length and 3.6 cm in diameter, stone (3.2 cm in diameter)

Tumor location: Center of the specimen

Tumor number: One

Tumor size: 2.8 x 2.5 x 2.3 cm

Satellite nodule: No

Gross type

HCC: Expanding nodular

Tumor necrosis: Yes (20 %)

Hemorrhage/peliosis: No

Portal vein invasion: Unknown

Bile duct invasion: Unknown

Peritumoral cirrhosis, micronodular

Gross photo present.

Blocks

T1-4 and TB, mass and surrounding tissue x 5

RM, mass and resection margin x 1

A and NB, remaining liver x 2

GB, gallbladder x 1

MICROSCOPIC:

Tumor type:

Hepatocellular carcinoma, trabecular and solid

Differentiation, II-III

Fibrous capsule formation: Yes

Surgical resection margin invasion: Free of tumor

Non-tumor liver pathology

Chronic hepatitis: Yes

Etiology: HBV

Grade, lobular: Minimal (grade 1)

Grade, portoperiportal: Minimal (grade 1)

Stage (fibrosis): Septal fibrosis (stage 3)

Dysplastic nodule: No

Ductal epithelial dysplasia: No

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

9/5/14

[page 2 of 2]
Other liver diseases: Steatosis, moderate

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703
Gallbladder, ectomy, chronic inflammation, cholelithiasis
T57000, P10, M43000, M30011

DIAGNOSIS:
Liver, segment 8, subsegmentectomy:
Hepatocellular carcinoma, moderately differentiated

Gallbladder, cholecystectomy:
Inflammation, chronic
Cholelithiasis

Suggestion :

Source: NCI Genomic Data Commons file ab36c957-5a75-46dd-a16c-819c65d55fde (TCGA-DD-AACS.EA952B6F-851C-4675-A933-80325945E7EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).